Somatic mutation profile of tumor specimen 0DSEKZ from CCDI case PBCGBH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.7 years (5,382 days).
Specimen 0DSEKZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd6aba8f-5f24-4e2f-abdf-71219066ddc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEKT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dd9567e-6670-4d5a-b054-cca08f9d3f6b

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPH | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 52/1536 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167299845, COSV57743752; called by muse, mutect2
- OR9G4 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 44/979 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as rs759952299, COSV57248107; called by muse, mutect2
- ZNF519 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 60/1140 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs1428967902; called by muse, mutect2
- CNTROB | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 24/490 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- FZD10 | c.1216C>A p.L406M | Missense Mutation (SNP) | VAF 27/555 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR183 | c.862A>T p.I288F | Missense Mutation (SNP) | VAF 34/1300 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); called by muse, mutect2
- RABEP1 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 118/893 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by mutect2, varscan2
- GCC2-AS1 | chr2:108534503 C>G | 5'Flank (SNP) | VAF 26/224 reads (12%) | called by muse, mutect2
